Gene-level copy-number profile of tumor specimen C3N-01651-01 from CPTAC case C3N-01651, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 58.8 years (21,464 days).
Specimen C3N-01651-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 916cfb7f-f037-4fdf-bde3-6cbd698a695a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01651-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/2377f553-c16f-46f7-b910-82af16c6fc54

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 513; copy number 1: 9,982; copy number 2: 46,953; copy number 3: 1,427; copy number 4: 25; copy number 5: 6; copy number 7: 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:34,489,002–34,490,571, 1 gene: HNRNPLP2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:57,598–64,116, 1 gene, copy number 7: OR4G11P.
- chr1:89,295–133,723, 1 gene, copy number 5 (within-gene range 3–5): AL627309.1.
- chr1:131,025–157,887, 5 genes, copy number 5: CICP27, AL627309.6, AL627309.7, AL627309.2, RNU6-1100P.

Autosomal genes at a single copy (total copy number 1): 7,644. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
